CCDI case PBCFZD — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/78032de9-3026-448f-8074-0e044069abd2

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Clear cell meningioma: ICD-O-3 morphology code: 9538/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.5 years (5,662 days).

Biospecimens (3 samples)
- Sample 0DR3L5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR3M1: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR3ME: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
